Somatic mutation profile of tumor specimen MP2PRT-PAVPXP-TMP1-A (aliquot MP2PRT-PAVPXP-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVPXP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (674 days).
Specimen MP2PRT-PAVPXP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58742e9c-1f41-4442-831e-c5d9979510f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVPXP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVPXP-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2736f1ed-ea5f-4b0c-b1e0-797b0e1e535e

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 22/373 reads (6%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- IRX4 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 35/650 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2
- PCDHGA9 | c.1385C>G p.P462R | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); called by muse, mutect2
- TNC | c.3414G>A p.T1138= | Silent (SNP) | VAF 20/390 reads (5%) | catalogued as COSV60787911; called by muse, mutect2
- ZNF469 | c.9333C>T p.P3111= (on ENST00000437464; = p.P3139= on NM_001367624.2) | Silent (SNP) | VAF 32/656 reads (5%) | catalogued as rs747613949; called by muse, mutect2
